Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A5XZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A5XZ-01A (Primary Tumor).

Sex: Female
D.O.B.:
MRN #:
Ref Physic:

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Right kidney, nephrectomy:

Tumor Characteristics:

1. Histologic type: Papillary renal cell carcinoma, see comment.
2. Tumor site: Right kidney.
3. Tumor focality: Unifocal.
4. Tumor size: 8.6 x 8.6 x 8.3 cm.
5. Macroscopic extent of tumor: Confined to kidney.
6. Microscopic extent of tumor: Confined to kidney.
7. Nuclear grade: Fuhrman grade 3/4.
8. Lymphovascular space invasion: Not identified..
9. Sarcomatoid features: Not identified.

Surgical Margin Status:

1. Margins uninvolved by carcinoma: Inked surface, ureter, vasculature.
2. Margins involved by carcinoma: None.

Lymph Node Status:

No lymph node present.

Other:

1. pTNM stage: pT2aNx.

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS C64.9
9/25/10/13

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stains performed on block #3 show the following results:

Cytokeratin 7: Positive in tumor.
CD68: Positive in foamy macrophages present in many papillary cores.

These findings along with the morphologic appearance are consistent with a papillary renal cell carcinoma.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: NONE GIVEN
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

Right kidney

SPECIMEN DATA

GROSS DESCRIPTION:

Container is labeled 1 right kidney. Received in formalin is a 613.5 gram nephrectomy specimen with a marked amount of attached yellow lobular fat. The kidney is 12.6 x 11.1 x 7.7 cm. The renal capsule is gray-tan, disrupted superiorly in a 4.5 cm in greatest dimensions focus. At the hilum, bulging from the capsule, there is a 8.6 x 8.6 x 8.3 cm soft, encapsulated mass. A portion of this capsule has been previously inked in blue and partially incised to collect Genomics research tissues: these Genomics tissues are received in yellow, green, and teal tissue cassettes, all labeled with the patient's name and respectively. Adjacent to the encapsulated mass at the hilum, there is an attached 5.7 cm long segment of ureter that is up to 0.3 cm in greatest diameter. The renal artery and vein segments at the margin are short, only up to 0.4 cm long, are patent, and unremarkable for tumor. Upon sectioning, the mass is well defined from the surrounding normal renal parenchyma. On cut section, the mass is soft, yellow-tan, necrotic and hemorrhagic. The mass does not involve the renal pelvis. The normal renal

parenchyma is tan to pink with an ill defined corticomedullary junction. The cortex averages 0.7 cm thick. The attached fat is unremarkable. No adrenal gland is identified. Representative sections are submitted in cassettes labeled as follows: A1--renal vein, arteries, and ureter at the margins; A2--disrupted portion of superior renal capsule; A3 and A4--mass to capsule; A5-A7--mass to renal pelvis; A8--mass to normal renal parenchyma.

Source: NCI Genomic Data Commons file 9f448fa0-c66b-4cad-abba-9c1957528b87 (TCGA-A4-A5XZ.BF101C5C-4A5F-4ECC-A8F3-0A9F21315564.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).